Somatic mutation profile of tumor specimen BA2619D (aliquot aq-BA2619D) from BEATAML1.0 case 2184, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.4 years (22,801 days).
Specimen BA2619D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c14771ee-f6b5-490b-a63a-c2c80b20ab8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2580D (Solid Tissue Normal), aliquot aq-BA2580D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cf3c87a-fbae-416b-b990-adb43b7b2e8a

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 3, Silent 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/421 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PHYKPL | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201105857, CM1212105; ClinVar: pathogenic; called by muse, mutect2
- L1CAM | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs782727308; called by muse, mutect2, varscan2
- LY6K | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV52832620; called by muse, mutect2
- POLI | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1309065928; called by muse, mutect2, varscan2
- SLC34A1 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs138027918; called by muse, mutect2, varscan2
- ANKRD60 | c.774T>A p.H258Q | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- CIZ1 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 3/54 reads (6%) | called by muse, mutect2
- GJA8 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 56/256 reads (22%) | called by muse, mutect2, varscan2
- HUWE1 | c.2764G>A p.V922I | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLXNA4 | c.979G>T p.G327* | Nonsense Mutation (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- PZP | c.2047_2048del p.K683Vfs*37 | Frame Shift Del (DEL) | VAF 42/208 reads (20%) | called by mutect2, pindel, varscan2
- RASA2 | c.2478A>C p.K826N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZNF563 | c.365T>G p.I122S | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- COL2A1 | c.1635C>T p.N545= | Silent (SNP) | VAF 31/217 reads (14%) | catalogued as rs141321284; ClinVar: likely benign; called by muse, mutect2, varscan2
- MN1 | c.3690C>T p.P1230= | Silent (SNP) | VAF 78/104 reads (75%) | catalogued as rs576242435; called by muse, varscan2
- NHLRC2 | c.1938A>G p.L646= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2
- PCCB | c.183+1757C>T | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
